CPTAC case C3N-00200 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b95cf6b8-f71b-4422-b8a7-ca5438b1ac66

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Dead; Days to death: 732 days (2.0 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 71.9 years (26,248 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 732 days (2.0 years); Progression or recurrence: yes; Days to recurrence: 722 days (2.0 years); Days to last follow up: 732 days (2.0 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 9 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 10; Margin status: Involved.

Follow-up (3 entries)
- Days to follow up: 408 days (1.1 years); Disease response: Tumor Free; ECOG performance status: 2.
- Days to follow up: 732 days (2.0 years); Disease response: With Tumor; ECOG performance status: 3.
- Days to follow up: 732 days (2.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 722 days (2.0 years); ECOG performance status: 3.

Other clinical attributes
- Weight: 131.6 kg; Height: 167.6 cm; BMI: 46.85; Diabetes treatment type: Insulin; Hormonal contraceptive use: Former User.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 8.3; Cigarettes per day: 5; Tobacco smoking onset year: 1962; Tobacco smoking quit year: 1995; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 33.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00200-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 407.8 mg.
- Sample C3N-00200-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 139 days; Initial weight: 227 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00200-22: Section location: Both anterior and posterior; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3N-00200-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 267.6 mg.
- Sample C3N-00200-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 139 days; Time between excision and freezing: 29 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00200-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 139 days; Method of sample procurement: Blood Draw.
- Sample C3N-00200-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
